Somatic mutation profile of tumor specimen ALCH-B47L-TTP1-A (aliquot ALCH-B47L-TTP1-A-1-0-D-A80E-36) from ALCHEMIST case ALCH-B47L, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 80.1 years (29,255 days).
Specimen ALCH-B47L-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 56809870-b0b6-4f25-9d5d-7655035381ce.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B47L-NB1-A (Blood Derived Normal), aliquot ALCH-B47L-NB1-A-1-0-D-A80E-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/09ecb6c6-7279-487a-b463-f2b0f68f8834

The open-access MAF lists 121 somatic variants for this specimen: 86 protein-altering or splice-affecting, 19 silent, 16 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 77, Silent 19, RNA 7, Intron 6, Nonsense Mutation 4, Splice Site 4, 5'UTR 2, 5'Flank 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>C p.G12A | Missense Mutation (SNP) | VAF 34/291 reads (12%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.723); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ABCA12 | c.3145C>A p.Q1049K (on ENST00000272895 / NM_173076.3; = p.Q731K on NM_015657.3) | Missense Mutation (SNP) | VAF 24/236 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV55958093; called by muse, mutect2, varscan2
- ABCB4 | c.2548T>C p.F850L | Missense Mutation (SNP) | VAF 18/432 reads (4%) | SIFT tolerated (0.25); PolyPhen benign (0.051); catalogued as CD159637; called by muse, mutect2
- ADAM2 | c.1391C>T p.S464L | Missense Mutation (SNP) | VAF 12/182 reads (7%) | SIFT tolerated (0.74); PolyPhen benign (0.012); catalogued as rs143851847; called by muse, mutect2
- APC2 | c.1390C>A p.R464S | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52019803; called by muse, varscan2
- C2orf78 | c.583A>T p.N195Y | Missense Mutation (SNP) | VAF 15/187 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as rs1286979368; called by muse, mutect2
- CDH23 | c.806G>T p.R269L | Missense Mutation (SNP) | VAF 10/128 reads (8%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.999); catalogued as COSV54931817; called by muse, mutect2
- CHGB | c.1316G>T p.R439M | Missense Mutation (SNP) | VAF 12/116 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); catalogued as rs771393741, COSV66759682, COSV66761431; called by muse, mutect2
- DCLK1 | c.923C>T p.P308L | Missense Mutation (SNP) | VAF 14/126 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.728); catalogued as COSV55190021, COSV99708495; called by muse, mutect2, varscan2
- DDR2 | c.2516G>C p.R839P | Missense Mutation (SNP) | VAF 60/326 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63370536; called by muse, varscan2
- DNAH5 | c.1296A>G p.I432M | Missense Mutation (SNP) | VAF 25/230 reads (11%) | SIFT tolerated (0.26); PolyPhen benign (0.144); catalogued as COSV99445693; called by muse, mutect2, varscan2
- EPYC | c.250G>T p.E84* | Nonsense Mutation (SNP) | VAF 19/149 reads (13%) | catalogued as COSV53800563; called by muse, mutect2, varscan2
- FGF1 | c.410G>T p.R137L | Missense Mutation (SNP) | VAF 27/156 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.665); catalogued as COSV100532335; called by muse, mutect2, varscan2
- GBP7 | c.143G>A p.R48H | Missense Mutation (SNP) | VAF 12/118 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.45); catalogued as rs148758371; called by muse, mutect2, varscan2
- GLI3 | c.2831C>G p.P944R | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67894973; called by muse, mutect2, varscan2
- GPR78 | c.905G>T p.R302L | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs368485565; called by muse, mutect2, varscan2
- GRIP1 | c.1436C>T p.P479L (on ENST00000359742 / NM_001379345.1; = p.P427L on NM_021150.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.738); catalogued as COSV54041062; called by muse, mutect2
- GRM4 | c.556C>A p.L186M | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65211099; called by muse, mutect2, varscan2
- HHIPL2 | c.1196C>A p.S399* | Nonsense Mutation (SNP) | VAF 8/40 reads (20%) | catalogued as COSV100597164; called by muse, mutect2
- NAV3 | c.3563G>T p.R1188L | Missense Mutation (SNP) | VAF 16/194 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.933); catalogued as COSV99887170; called by muse, mutect2
- OR2L13 | c.793C>T p.R265C | Missense Mutation (SNP) | VAF 22/392 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.01); catalogued as rs553614392, COSV63560530; called by muse, mutect2
- OTOG | c.2091C>A p.D697E | Missense Mutation (SNP) | VAF 5/79 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs886209740; called by muse, mutect2
- PKHD1L1 | c.11278C>A p.Q3760K | Missense Mutation (SNP) | VAF 22/256 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV65742028; called by muse, mutect2
- PTPRT | c.3677G>T p.G1226V | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99049580; called by mutect2, varscan2
- PTPRT | c.3096del p.K1033Rfs*48 | Frame Shift Del (DEL) | VAF 7/51 reads (14%) | catalogued as COSV62023736; called by mutect2, pindel, varscan2
- RGPD4 | c.3386C>A p.A1129E | Missense Mutation (SNP) | VAF 60/725 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV61746525; called by muse, mutect2
- RNASET2 | c.709G>T p.G237C | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as rs767307679; called by muse, mutect2, varscan2
- SKOR2 | c.746C>T p.A249V | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.689); catalogued as COSV101247198; called by muse, mutect2, varscan2
- STT3A | c.100C>A p.R34S | Missense Mutation (SNP) | VAF 20/250 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67064540; called by muse, mutect2
- TCHHL1 | c.1369C>A p.P457T | Missense Mutation (SNP) | VAF 22/176 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.046); catalogued as COSV100916548; called by muse, mutect2, varscan2
- TMPRSS11D | c.65T>A p.I22N | Missense Mutation (SNP) | VAF 18/244 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.219); catalogued as COSV52225171; called by muse, mutect2
- WNK3 | c.3841C>T p.R1281W | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.894); catalogued as rs377088498, COSV63614425; called by muse, mutect2
- ZMAT1 | c.289G>T p.V97L | Missense Mutation (SNP) | VAF 11/200 reads (6%) | SIFT tolerated (0.25); PolyPhen benign (0.045); catalogued as rs1224083749; called by muse, mutect2
- ZNF253 | c.700G>T p.G234C | Missense Mutation (SNP) | VAF 33/323 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63037132; called by muse, mutect2
- ACSL4 | c.2029C>A p.P677T (on ENST00000340800 / NM_022977.2; = p.P636T on NM_004458.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.492); called by muse, mutect2, varscan2
- AKAP6 | c.3009T>A p.S1003R | Missense Mutation (SNP) | VAF 22/148 reads (15%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.601); called by mutect2, varscan2
- ARHGAP20 | c.2908G>A p.E970K | Missense Mutation (SNP) | VAF 9/162 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.326); called by muse, mutect2
- ARMCX5 | c.1442C>A p.P481H | Missense Mutation (SNP) | VAF 7/110 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.005); called by muse, mutect2
- BMPER | c.284T>C p.I95T | Missense Mutation (SNP) | VAF 17/203 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.003); called by muse, mutect2
- C8A | c.1121C>A p.T374K | Missense Mutation (SNP) | VAF 54/566 reads (10%) | SIFT tolerated (0.78); PolyPhen benign (0.003); called by muse, mutect2
- CANT1 | c.354G>T p.R118S | Missense Mutation (SNP) | VAF 18/222 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.044); called by muse, mutect2
- CEP128 | c.944A>T p.Q315L | Missense Mutation (SNP) | VAF 28/221 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); called by muse, mutect2, varscan2
- CLASP1 | c.2901-1G>T p.X967_splice | Splice Site (SNP) | VAF 16/178 reads (9%) | called by muse, mutect2
- CLCN5 | c.1877G>C p.R626P | Missense Mutation (SNP) | VAF 12/122 reads (10%) | SIFT tolerated (0.28); PolyPhen benign (0.092); called by muse, mutect2, varscan2
- COL9A1 | c.1139C>T p.P380L | Missense Mutation (SNP) | VAF 15/512 reads (3%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.652); called by muse, mutect2
- CYLD | c.1271C>T p.T424I | Missense Mutation (SNP) | VAF 31/285 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.216); called by muse, mutect2, varscan2
- FTSJ1 | c.501C>G p.Y167* | Nonsense Mutation (SNP) | VAF 8/92 reads (9%) | called by muse, mutect2
- FTSJ3 | c.817-1G>T p.X273_splice | Splice Site (SNP) | VAF 9/104 reads (9%) | called by muse, mutect2
- GSAP | c.22G>T p.D8Y | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.385); called by muse, varscan2
- HUWE1 | c.4851G>C p.W1617C | Missense Mutation (SNP) | VAF 24/182 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KIF4A | c.2382A>T p.K794N | Missense Mutation (SNP) | VAF 6/69 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2
- KIR2DS4 | c.156T>A p.D52E | Missense Mutation (SNP) | VAF 15/132 reads (11%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- KLK12 | c.693C>A p.Y231* | Nonsense Mutation (SNP) | VAF 9/100 reads (9%) | called by muse, mutect2
- LANCL3 | c.810G>T p.Q270H | Missense Mutation (SNP) | VAF 31/330 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); called by muse, mutect2
- LIN28B | c.424T>A p.C142S | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2
- MDN1 | c.6276G>A p.M2092I | Missense Mutation (SNP) | VAF 6/130 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.14); called by muse, mutect2
- MSH3 | c.3057A>T p.K1019N | Missense Mutation (SNP) | VAF 16/392 reads (4%) | SIFT tolerated (0.16); PolyPhen benign (0.021); called by muse, mutect2
- MTR | c.1173G>T p.M391I | Missense Mutation (SNP) | VAF 32/470 reads (7%) | SIFT tolerated (0.2); PolyPhen benign (0.01); called by muse, mutect2
- MTUS2 | c.3073G>T p.G1025C | Missense Mutation (SNP) | VAF 9/89 reads (10%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.923); called by muse, mutect2, varscan2
- OR2L13 | c.355T>A p.Y119N | Missense Mutation (SNP) | VAF 23/282 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); called by muse, mutect2
- OR5B12 | c.464C>A p.S155Y | Missense Mutation (SNP) | VAF 18/292 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.707); called by muse, mutect2
- OSBP | c.1787G>A p.G596D | Missense Mutation (SNP) | VAF 6/94 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- OTOGL | c.4018G>T p.V1340F (on ENST00000547103; = p.V1331F on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/167 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.583); called by muse, mutect2, varscan2
- PCDH15 | c.3031G>C p.D1011H | Missense Mutation (SNP) | VAF 21/348 reads (6%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.599); called by muse, mutect2
- PDE1C | c.1040A>T p.Q347L | Missense Mutation (SNP) | VAF 16/220 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.564); called by muse, mutect2
- PDE4D | c.1172A>G p.E391G (on ENST00000340635 / NM_001104631.2; = p.E255G on NM_006203.4) | Missense Mutation (SNP) | VAF 5/82 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.965); called by muse, mutect2
- PLA1A | c.74-1G>C p.X25_splice | Splice Site (SNP) | VAF 5/45 reads (11%) | called by muse, mutect2, varscan2
- PLBD1 | c.595G>T p.V199F | Missense Mutation (SNP) | VAF 6/79 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.11); called by muse, mutect2
- PLOD2 | c.616-2A>T p.X206_splice | Splice Site (SNP) | VAF 8/216 reads (4%) | called by muse, mutect2
- PRKDC | c.377C>T p.P126L | Missense Mutation (SNP) | VAF 18/109 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- RBPJL | c.1471C>A p.P491T | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT tolerated (0.43); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- RP1 | c.1799A>G p.E600G | Missense Mutation (SNP) | VAF 11/109 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- RPS6KA6 | c.1669A>T p.S557C | Missense Mutation (SNP) | VAF 14/278 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.762); called by muse, mutect2
- SCML2 | c.2083A>G p.K695E | Missense Mutation (SNP) | VAF 17/187 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SLC25A38 | c.833G>T p.R278L | Missense Mutation (SNP) | VAF 13/167 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SLC25A52 | c.211T>A p.Y71N (on ENST00000672005; = p.Y61N on NM_001034172.4) | Missense Mutation (SNP) | VAF 14/104 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.149); called by muse, mutect2, varscan2
- SLC9A4 | c.1487G>T p.R496L | Missense Mutation (SNP) | VAF 17/153 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.509); called by muse, mutect2
- TDRD5 | c.2904C>A p.S968R | Missense Mutation (SNP) | VAF 14/89 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.012); called by mutect2, varscan2
- TENM3 | c.2858G>A p.S953N | Missense Mutation (SNP) | VAF 20/193 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.05); called by muse, mutect2
- THAP9 | c.1858A>T p.R620W | Missense Mutation (SNP) | VAF 29/208 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.611); called by muse, mutect2, varscan2
- VIT | c.1224C>A p.D408E (on ENST00000389975 / NM_001177969.1; = p.D423E on NM_053276.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- WDR87 | c.4606C>G p.Q1536E | Missense Mutation (SNP) | VAF 10/124 reads (8%) | SIFT tolerated (0.9); PolyPhen benign (0.034); called by muse, mutect2
- WFDC8 | c.602G>A p.C201Y | Missense Mutation (SNP) | VAF 14/122 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ZEB1 | c.3141G>T p.M1047I | Missense Mutation (SNP) | VAF 42/524 reads (8%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0); called by muse, mutect2
- ZMYM3 | c.436C>A p.P146T | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- ZZEF1 | c.6852G>T p.R2284S | Missense Mutation (SNP) | VAF 16/132 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.092); called by muse, mutect2, varscan2
- ATP1A2 | c.165G>A p.V55= | Silent (SNP) | VAF 18/182 reads (10%) | catalogued as COSV63403807; called by muse, mutect2
- BAIAP3 | c.558A>T p.R186= | Silent (SNP) | VAF 6/47 reads (13%) | called by muse, mutect2, varscan2
- CROT | c.585G>T p.L195= | Silent (SNP) | VAF 17/225 reads (8%) | catalogued as COSV58974190; called by muse, mutect2
- CSNK1D | c.279C>T p.F93= | Silent (SNP) | VAF 8/140 reads (6%) | catalogued as rs1394727192, COSV53925160; called by muse, mutect2
- DDX56 | c.495G>T p.V165= | Silent (SNP) | VAF 7/136 reads (5%) | called by muse, mutect2
- EFEMP1 | c.114G>A p.V38= | Silent (SNP) | VAF 14/438 reads (3%) | called by muse, mutect2
- GNB5 | c.1077G>T p.R359= (on ENST00000261837 / NM_016194.4; = p.R317= on NM_006578.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 5/104 reads (5%) | called by muse, mutect2
- GPR152 | c.849G>A p.L283= | Silent (SNP) | VAF 8/94 reads (9%) | catalogued as COSV56885752; called by muse, mutect2
- IL13RA2 | c.372A>G p.A124= | Silent (SNP) | VAF 7/63 reads (11%) | called by muse, mutect2
- MICAL3 | c.3087C>T p.H1029= | Silent (SNP) | VAF 4/44 reads (9%) | catalogued as rs768887848; called by mutect2, varscan2
- MKI67 | c.3847T>C p.L1283= | Silent (SNP) | VAF 10/110 reads (9%) | called by muse, mutect2
- OR2T3 | c.339T>A p.A113= | Silent (SNP) | VAF 17/170 reads (10%) | catalogued as rs1048315531; called by muse, mutect2
- PCDHB2 | c.642C>T p.L214= | Silent (SNP) | VAF 6/76 reads (8%) | called by muse, mutect2
- PHF24 | c.573C>A p.I191= | Silent (SNP) | VAF 8/106 reads (8%) | catalogued as COSV99646256; called by muse, mutect2
- POU2F1 | c.798G>A p.Q266= (on ENST00000541643 / NM_001365848.1; = p.Q289= on NM_002697.4) | Silent (SNP) | VAF 12/244 reads (5%) | called by muse, mutect2
- PPIE | c.456G>T p.P152= | Silent (SNP) | VAF 16/127 reads (13%) | called by muse, mutect2, varscan2
- SHROOM4 | c.3159G>A p.L1053= | Silent (SNP) | VAF 16/120 reads (13%) | catalogued as COSV99173316; called by muse, mutect2, varscan2
- SMOX | c.111G>T p.L37= | Silent (SNP) | VAF 11/107 reads (10%) | called by muse, mutect2
- TSSK1B | c.954A>C p.A318= | Silent (SNP) | VAF 8/74 reads (11%) | catalogued as rs764482166; called by muse, mutect2, varscan2
- AC133552.2 | n.343G>A | RNA (SNP) | VAF 7/100 reads (7%) | called by muse, mutect2
- AP000769.3 | chr11:65504325 G>A | 5'Flank (SNP) | VAF 7/92 reads (8%) | called by muse, mutect2
- BET1P1 | n.224C>T | RNA (SNP) | VAF 6/82 reads (7%) | called by muse, mutect2
- FOLH1B | n.1133G>T | RNA (SNP) | VAF 13/258 reads (5%) | called by muse, mutect2
- GIMAP4 | c.58+38G>A | Intron (SNP) | VAF 8/59 reads (14%) | catalogued as COSV99751143; called by muse, mutect2, varscan2
- LILRA1 | c.-22C>A | 5'UTR (SNP) | VAF 5/50 reads (10%) | called by muse, mutect2, varscan2
- MIR19A | n.80T>G | RNA (SNP) | VAF 20/97 reads (21%) | called by muse, mutect2, varscan2
- OR51F5P | n.721G>T | RNA (SNP) | VAF 15/114 reads (13%) | called by muse, mutect2, varscan2
- OR51F5P | n.722G>T | RNA (SNP) | VAF 16/117 reads (14%) | called by muse, mutect2, varscan2
- RPGR | c.2520+287G>T | Intron (SNP) | VAF 4/25 reads (16%) | called by muse, varscan2
- RPSAP52 | n.617C>T | RNA (SNP) | VAF 10/88 reads (11%) | catalogued as rs770149925; called by muse, mutect2, varscan2
- SAMSN1 | c.235+217T>C | Intron (SNP) | VAF 10/122 reads (8%) | called by muse, mutect2
- SLC17A9 | c.911-26G>T | Intron (SNP) | VAF 4/28 reads (14%) | catalogued as rs758364896; called by mutect2, varscan2
- SPG7 | c.2161-27A>T | Intron (SNP) | VAF 11/77 reads (14%) | called by muse, mutect2, varscan2
- TEPP | c.785+15C>T | Intron (SNP) | VAF 3/13 reads (23%) | called by muse, varscan2
- TLR7 | c.-27A>T | 5'UTR (SNP) | VAF 9/110 reads (8%) | called by muse, mutect2
